Gene-level copy-number profile of tumor specimen TCGA-58-8387-01A from TCGA case TCGA-58-8387, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIA; Age at diagnosis: 60.1 years (21,952 days).
Specimen TCGA-58-8387-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.3e578599-7e6b-4b4c-83eb-e6d42b6c0b02.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-58-8387-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/8c7ac1de-9d87-4570-8a2b-293c59bfc78c

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 4; copy number 1: 16,024; copy number 2: 36,101; copy number 3: 6,114; copy number 4: 378; copy number 5: 578; copy number 6: 267; copy number 7: 159; copy number 9: 6; copy number 11: 62; copy number 12: 72; copy number 18: 42; copy number 29: 7.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-58-8387-01A-11D-2292-01): tumor purity 0.38, ploidy 1.99, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 4 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:4,633,065–4,788,584, 2 genes: AC022068.1, PAICSP4.
- chr11:81,015,849–81,431,520, 2 genes (within-gene range 0–1): AP003398.2, AP003464.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,193 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:57,755,428–71,064,743, 268 genes, copy number 5–29 (within-gene range 2–29) (broad region; genes not listed).
- chr3:164,670,878–198,222,513, 636 genes, copy number 5–6 (broad region; genes not listed).
- chr4:73,052,362–74,388,749, 35 genes, copy number 11: COX18, ANKRD17, HMGA1P2, AC053527.2, AC053527.1, AC108157.1, ALB, AFP, AFM, LINC02499, AC074250.1, RASSF6, UMLILO, CXCL8, AC112518.1, CXCL6, PPBPP1, PF4V1, CXCL1, HNRNPA1P55, CXCL1P1, PF4, PPBP, CXCL5, AC097709.1, RN7SL218P, CXCL3, PPBPP2, AC093677.3, AC093677.1, CXCL2, MTHFD2L, AC093677.2, EPGN, EREG.
- chr8:12,765,849–12,818,291, 2 genes, copy number 6: AC123777.1, LINC00681.
- chr8:14,084,845–15,238,431, 1 gene, copy number 7 (within-gene range 2–7): SGCZ.
- chr8:14,690,382–15,325,569, 4 genes, copy number 7: AC040926.1, MIR383, AC084838.1, AC103851.1.
- chr8:34,784,028–39,417,378, 93 genes, copy number 7–12 (broad region; genes not listed).
- chr8:42,416,475–42,555,195, 4 genes, copy number 12 (within-gene range 2–12): SLC20A2, AC093367.1, AC090739.1, SMIM19.
- chr9:5,450,503–5,629,748, 4 genes, copy number 12 (within-gene range 1–12): CD274, AL162253.2, PDCD1LG2, AL162253.1.
- chr11:34,915,829–38,014,141, 40 genes, copy number 5 (within-gene range 1–5): PDHX, MIR1343, AL356215.1, CD44, CD44-AS1, AL133330.1, SLC1A2, SLC1A2-AS1, AC090625.1, AC090625.2, PAMR1, AL135934.1, FJX1, AL138812.1, TRIM44, AC090692.2, KRT18P14, AC090692.3, AC090692.1, LDLRAD3, AL136146.1, AL136146.2, RPL12P31, MIR3973, AC129502.1, COMMD9, PRR5L, AC087277.1, AC087277.2, AC009656.1, TRAF6, AC061999.1, RAG1, RAG2, IFTAP, AC104042.1, AC061997.1, RPL7AP56, LINC02760, AC103798.1.
- chr11:69,294,151–72,290,688, 105 genes, copy number 7 (broad region; genes not listed).
- chr11:72,302,139–72,302,965, 1 gene, copy number 7: AP000593.3.

Autosomal genes at a single copy (total copy number 1): 13,637. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
